Gene-level copy-number profile of tumor specimen TCGA-QK-A8ZB-01A from TCGA case TCGA-QK-A8ZB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 69.0 years (25,192 days).
Specimen TCGA-QK-A8ZB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.30d40a67-9516-4633-a696-c5187a2d55b5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QK-A8ZB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d48ee1ec-dde4-48e0-9607-13e91f0d8a6c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 228; copy number 1: 15,477; copy number 2: 41,657; copy number 3: 1,863; copy number 4: 402; copy number 5: 185; copy number 10: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QK-A8ZB-01A-11D-A390-01): tumor purity 0.46, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 228 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:724,194–1,580,747, 14 genes (within-gene range 0–1): AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO.
- chr4:185,918,140–186,500,997, 14 genes (within-gene range 0–1): AC096659.1, RNU4-64P, TLR3, FAM149A, AC104070.1, RPSAP70, ORAOV1P1, FLJ38576, CYP4V2, KLKB1, F11, F11-AS1, AC109517.1, SLC25A5P6.
- chr4:187,408,232–188,681,051, 19 genes (within-gene range 0–1): LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1, ADAM20P3, AC108073.3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3.
- chr8:5,848,697–5,854,977, 2 genes: AC087369.1, AC087369.2.
- chr21:10,328,411–23,968,747, 179 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 191 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:33,338,867–43,030,535, 191 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,058. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
